MMRF case MMRF_1629 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2c15a017-e507-47d0-9ee2-ead299d542a9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.3 years (22,372 days); ISS stage: II; Days to last known disease status: 1,161 days (3.2 years); Days to last follow up: 1,161 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 189 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 206 days; Days to treatment end: 206 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 350 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 0): M Protein 4.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.877 mg/dL; Immunoglobulin G 50 g/L; Beta 2 Microglobulin 3.52 µg/mL; Lactate Dehydrogenase 5.22 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 79.6 µmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 11.3 g/dL; Glucose 4.73 mmol/L; C-Reactive Protein 0.84 mg/dL.
- Day 84: M Protein 0.9 g/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.29 mmol/L.
- Day 147 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 6.16 mmol/L.
- Day 238 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.54 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 3.04 g/L; Immunoglobulin M 0.526 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 283 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 3.8 mmol/L.
- Day 336 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.592 g/L; Hemoglobin 9.24 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 4.13 mmol/L.
- Day 420 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 3.8 mmol/L.
- Day 532 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 4.79 mmol/L.
- Day 644: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.16 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 2.27 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.3 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 3.96 mmol/L.
- Day 699: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 2.42 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 3.1 µg/mL; Hemoglobin 9.36 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.
- Day 783: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 2.11 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.1 µg/mL; Hemoglobin 9.05 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 4.73 mmol/L.
- Day 867: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.2 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 79.6 µmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Glucose 4.79 mmol/L.
- Day 951: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.9 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 2.5 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 1.3 µg/mL; Hemoglobin 8.68 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.17 mmol/L.
- Day 1,077: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.62 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 2.1 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 2 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.35 mmol/L.
- Day 1,161: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.06 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 2.61 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -4: Weight: 109 kg; Height: 173 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1629_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1629_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
